Somatic mutation profile of tumor specimen TCGA-MP-A4T4-01A (aliquot TCGA-MP-A4T4-01A-11D-A25L-08) from TCGA case TCGA-MP-A4T4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 68.6 years (25,052 days).
Specimen TCGA-MP-A4T4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc49004c-58d9-42ad-891c-805c6b43d947.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4T4-10A (Blood Derived Normal), aliquot TCGA-MP-A4T4-10A-01D-A25L-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/802dd560-e426-4819-97be-2879ea30bf81

The open-access MAF lists 413 somatic variants for this specimen: 318 protein-altering or splice-affecting, 89 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 279, Silent 89, Nonsense Mutation 22, Frame Shift Del 10, Intron 4, Splice Site 3, Frame Shift Ins 2, RNA 2, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 3/19 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ABCA5 | c.4244G>T p.R1415L | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV101201274; called by muse, mutect2
- ABCB7 | c.2242G>A p.G748R (on ENST00000373394 / NM_001271696.3; = p.G749R on NM_004299.6) | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99504800; called by muse, mutect2
- ABCG2 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs969464418, COSV99420130; called by muse, mutect2, varscan2
- ACACB | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV100623276; called by muse, mutect2, varscan2
- ACAN | c.5839C>A p.Q1947K | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); catalogued as COSV100719205; called by muse, mutect2, varscan2
- ADAMTS12 | c.2993C>G p.S998C | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV100711648; called by muse, mutect2, varscan2
- ADAMTS17 | c.641G>T p.R214M | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99170665; called by muse, varscan2
- ADCY9 | c.1204G>T p.G402C | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570830; called by muse, mutect2
- ADH1B | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 41/342 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV100520866; called by muse, mutect2, varscan2
- AGAP3 | c.1850A>T p.K617M (on ENST00000622464; = p.K653M on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257414; called by muse, mutect2, varscan2
- AKAP12 | c.4581T>A p.S1527R | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99484368; called by muse, mutect2, varscan2
- ALK | c.1905C>A p.Y635* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV66559410; called by muse, mutect2, varscan2
- AMPD1 | c.773G>T p.S258I | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV100815218; called by muse, mutect2
- ARHGAP36 | c.1591C>G p.R531G | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.085); catalogued as COSV52267090, COSV99358205; called by muse, mutect2, varscan2
- ARHGEF6 | c.2257G>T p.V753L | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1314819867, COSV99166712; called by muse, mutect2, varscan2
- ARNTL2 | c.1651G>C p.V551L | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99668062; called by muse, mutect2
- ASXL3 | c.5590G>C p.G1864R | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.325); catalogued as COSV99326452; called by muse, mutect2
- ATF6 | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100909474; called by muse, mutect2, varscan2
- ATG7 | c.1411G>T p.V471F | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs767392709, COSV100607956; called by muse, mutect2, varscan2
- ATRNL1 | c.881del p.P294Qfs*10 | Frame Shift Del (DEL) | VAF 18/160 reads (11%) | catalogued as COSV100746746; called by mutect2, pindel, varscan2
- BAZ1B | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV100290110; called by muse, mutect2
- BLOC1S3 | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99135368; called by muse, varscan2
- BPTF | c.6163G>A p.A2055T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV58835475; called by muse, mutect2, varscan2
- BTK | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100437909; called by muse, mutect2, varscan2
- C1QL4 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as COSV99227012; called by muse, mutect2, varscan2
- C7orf57 | c.58T>A p.W20R | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100817209, COSV100817324; called by muse, mutect2
- CACNA1E | c.5580C>A p.A1860= | Splice Region (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100705136; called by muse, mutect2, varscan2
- CAP2 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100012842, COSV57737220; called by muse, mutect2, varscan2
- CATSPERG | c.2834+1G>T p.X945_splice | Splice Site (SNP) | VAF 48/523 reads (9%) | catalogued as COSV99286904; called by muse, mutect2
- CCDC14 | c.1846G>T p.D616Y (on ENST00000488653; = p.D568Y on NM_022757.5) | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100113249, COSV100113449; called by muse, mutect2, varscan2
- CCDC81 | c.31G>T p.D11Y | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV99564858; called by muse, mutect2
- CCR2 | c.905C>G p.P302R | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52748132, COSV99432776; called by muse, mutect2, varscan2
- CD4 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV99163893; called by muse, mutect2
- CDH10 | c.700C>A p.Q234K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.062); catalogued as COSV99077797; called by muse, mutect2, varscan2
- CDHR2 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs777738616, COSV56135649, COSV56138665; called by muse, mutect2, varscan2
- CDHR2 | c.3640T>A p.Y1214N | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99991710, COSV99992158; called by muse, mutect2, varscan2
- CEL | c.515G>C p.G172A (on ENST00000673714; = p.G169A on NM_001807.6) | Missense Mutation (SNP) | VAF 18/257 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100672775; called by muse, mutect2
- CERS3 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.355); catalogued as rs968377426, COSV99432789; called by muse, mutect2, varscan2
- CETP | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99570335; called by muse, mutect2
- CHD5 | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV52412415; called by muse, mutect2, varscan2
- CHD8 | c.1832A>T p.E611V (on ENST00000646647 / NM_001170629.2; = p.E332V on NM_020920.4) | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV101303210; called by muse, mutect2, varscan2
- CLEC5A | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.935); catalogued as COSV101407799; called by muse, mutect2, varscan2
- CNGA4 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101171873; called by muse, mutect2, varscan2
- CNTN5 | c.2459G>T p.G820V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV99681052; called by muse, mutect2
- CNTN5 | c.2590C>A p.Q864K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99674128; called by muse, mutect2
- CNTNAP2 | c.1906G>T p.V636L | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV62185441, COSV62244521; called by muse, mutect2, varscan2
- COL11A1 | c.4597C>A p.P1533T | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100617963; called by muse, mutect2, varscan2
- COL11A1 | c.3925-1G>T p.X1309_splice | Splice Site (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100617964, COSV104421792, COSV62187293; called by muse, mutect2
- COL1A2 | c.2566G>T p.G856* | Nonsense Mutation (SNP) | VAF 12/79 reads (15%) | catalogued as CM062552, COSV99801024; called by muse, mutect2, varscan2
- COL3A1 | c.3233C>A p.P1078H | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100483685; called by muse, mutect2, varscan2
- CPS1 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 40/333 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.462); catalogued as COSV99244021; called by muse, mutect2, varscan2
- CPXCR1 | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99342408; called by muse, mutect2, varscan2
- CRNN | c.556T>C p.S186P | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.139); catalogued as COSV99664393; called by muse, mutect2
- CSMD1 | c.7609G>T p.V2537L (on ENST00000520002; = p.V2536L on NM_033225.6) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as COSV100153382; called by muse, mutect2, varscan2
- CSMD1 | c.6433G>T p.A2145S (on ENST00000520002; = p.A2144S on NM_033225.6) | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV100153385; called by muse, mutect2, varscan2
- CSMD3 | c.8851G>T p.G2951* (on ENST00000297405 / NM_001363185.1; = p.G2782* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 15/166 reads (9%) | catalogued as COSV99846819; called by muse, mutect2
- CTTN | c.1300A>T p.R434* | Nonsense Mutation (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100098325; called by muse, mutect2
- CYFIP2 | c.2692G>T p.E898* (on ENST00000616178 / NM_001291722.2; = p.E873* on NM_014376.4) | Nonsense Mutation (SNP) | VAF 10/59 reads (17%) | catalogued as COSV100400505; called by muse, mutect2, varscan2
- DCAF12L1 | c.1064C>A p.S355* | Nonsense Mutation (SNP) | VAF 10/98 reads (10%) | catalogued as COSV100948387; called by muse, mutect2
- DCAF4L2 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60480562, COSV60481042; called by muse, mutect2, varscan2
- DNAH3 | c.9343C>A p.L3115M | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as COSV99770433; called by muse, mutect2, varscan2
- DNAH9 | c.1866G>T p.Q622H | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV99307939; called by muse, mutect2
- DNAJB6 | c.936G>T p.Q312H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV100056011; called by muse, mutect2, varscan2
- DNM3 | c.925C>A p.H309N | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100798632; called by muse, mutect2, varscan2
- DSG1 | c.445G>T p.D149Y | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936538; called by muse, mutect2
- DVL3 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV57457736; called by muse, mutect2
- DYSF | c.4904G>C p.C1635S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99246110, COSV99250272; called by muse, mutect2, varscan2
- EGFLAM | c.2651C>A p.P884H (on ENST00000354891 / NM_001205301.2; = p.P876H on NM_152403.4) | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100380763, COSV59296545; called by muse, mutect2
- EMD | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100877418; called by muse, mutect2
- ENPP3 | c.2393C>A p.P798H | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100718019; called by muse, mutect2
- EPHA5 | c.2450C>A p.S817Y | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56655910, COSV99901102; called by muse, mutect2, varscan2
- EPM2A | c.579G>T p.Q193H | Missense Mutation (SNP) | VAF 18/151 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100837638; called by muse, mutect2, varscan2
- ERCC6L | c.2980C>A p.H994N | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.018); catalogued as COSV100559247; called by muse, mutect2, varscan2
- EXPH5 | c.494A>T p.Q165L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV99762160; called by muse, mutect2
- EYA1 | c.836C>A p.T279K | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as COSV100380240; called by muse, mutect2, varscan2
- F8 | c.5935G>A p.G1979R | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100811903; called by muse, mutect2, varscan2
- FAM47B | c.670C>A p.R224S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as COSV100264611, COSV61452636; called by muse, mutect2, varscan2
- FAT4 | c.7328G>T p.G2443V | Missense Mutation (SNP) | VAF 33/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58678276; called by muse, mutect2, varscan2
- FCGR1A | c.258G>C p.Q86H | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs781924551, COSV100977314, COSV64986002; called by muse, mutect2, varscan2
- FCRL4 | c.1100C>G p.P367R | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.19); catalogued as COSV99620399; called by muse, mutect2, varscan2
- FER1L6 | c.448G>T p.V150F | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101206171; called by muse, mutect2, varscan2
- FGF21 | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs200208273; called by muse, mutect2, varscan2
- FLNB | c.6836C>T p.P2279L | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.999); catalogued as rs937831006, COSV99914716; called by muse, mutect2
- FRMPD1 | c.1336C>A p.R446S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100899625; called by muse, mutect2, varscan2
- FZD2 | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV100190785; called by muse, mutect2
- GALNTL6 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101560527, COSV72493739; called by muse, mutect2, varscan2
- GML | c.115G>C p.D39H | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); catalogued as COSV99638600; called by muse, mutect2
- GNAT3 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV101242419; called by mutect2, varscan2
- GPATCH3 | c.181G>C p.A61P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV100658910; called by muse, mutect2, varscan2
- GPR158 | c.2636C>A p.S879* | Nonsense Mutation (SNP) | VAF 26/167 reads (16%) | catalogued as COSV100894257; called by muse, mutect2, varscan2
- GRID2 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56221538, COSV99946399; called by muse, mutect2, varscan2
- GRK7 | c.185A>T p.Q62L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.598); catalogued as COSV99380241; called by muse, mutect2, varscan2
- GRM8 | c.293T>A p.L98Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100285837; called by muse, mutect2, varscan2
- HCN1 | c.2224C>A p.Q742K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.074); catalogued as COSV100302167; called by muse, mutect2, varscan2
- HCN1 | c.1065C>A p.H355Q | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV100302169; called by muse, mutect2, varscan2
- HID1 | c.1802G>C p.G601A | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.081); catalogued as COSV100173042; called by muse, mutect2
- HPS5 | c.1540G>C p.E514Q (on ENST00000349215 / NM_181507.2; = p.E400Q on NM_007216.4) | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV100752364; called by muse, mutect2, varscan2
- HYAL1 | c.554G>A p.G185D | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as rs1553713196, COSV99807878; called by muse, mutect2
- IGSF11 | c.344C>A p.T115N (on ENST00000393775 / NM_001015887.3; = p.T114N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100677854; called by muse, mutect2, varscan2
- INTU | c.1763G>T p.R588I | Missense Mutation (SNP) | VAF 26/205 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100081373, COSV58874297; called by muse, mutect2, varscan2
- ITFG2 | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99958335; called by muse, mutect2, varscan2
- ITGAD | c.335G>T p.R112I | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101210572; called by muse, mutect2, varscan2
- ITGB8 | c.1177del p.E393Kfs*30 | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as COSV56007342; called by mutect2, pindel, varscan2
- ITPR1 | c.4030G>A p.V1344M (on ENST00000354582; = p.V1329M on NM_002222.7) | Missense Mutation (SNP) | VAF 22/272 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.884); catalogued as rs1171512407, COSV56980120, COSV57000909; called by muse, mutect2
- JAG2 | c.2599G>A p.G867R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1334041983, COSV59312659; called by muse, mutect2, varscan2
- KANSL1 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99294919; called by muse, mutect2, varscan2
- KDM4D | c.1025G>T p.R342L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV100624359, COSV58633904; called by muse, mutect2, varscan2
- KHDC1 | c.666C>A p.Y222* (on ENST00000370384 / NM_001251874.2; = p.Y149* on NM_030568.5) | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100001968, COSV57615204; called by muse, mutect2, varscan2
- KIF21A | c.1060G>C p.D354H | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100735634; called by muse, mutect2
- KIF25 | c.1034G>A p.R345K (on ENST00000354419 / NM_030615.2; = p.R293K on NM_005355.3) | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs931328329, COSV100596487; called by muse, mutect2
- KIR2DL1 | c.499C>A p.H167N | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV99383633; called by muse, mutect2, varscan2
- KLHL4 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.288); catalogued as COSV100909973, COSV100910137; called by muse, mutect2
- KMT2A | c.8509A>T p.N2837Y | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100629775; called by muse, mutect2
- KRTAP1-5 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV100721404; called by mutect2, varscan2
- KRTAP19-4 | c.237C>G p.F79L | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1354638748, COSV100478592; called by muse, mutect2
- L1CAM | c.2414G>A p.G805D | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100649455, COSV62828037; called by muse, mutect2, varscan2
- LAMA2 | c.1486G>T p.D496Y | Missense Mutation (SNP) | VAF 4/79 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV101370815; called by muse, mutect2
- LAMA2 | c.8245-1G>C p.X2749_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV101370816; called by muse, mutect2, varscan2
- LGALS9 | c.1034G>A p.G345E (on ENST00000395473 / NM_009587.3; = p.G313E on NM_002308.4) | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.989); catalogued as COSV100119529; called by muse, mutect2
- LIG3 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 25/279 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV99253120; called by muse, mutect2
- LILRA2 | c.1444G>T p.G482W (on ENST00000391738 / NM_001130917.3; = p.G465W on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV52191030, COSV99253905; called by muse, mutect2, varscan2
- LRP1B | c.11188C>A p.L3730I | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.967); catalogued as COSV101255797, COSV101260540; called by muse, mutect2, varscan2
- LRTM2 | c.924G>T p.M308I | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV99766454; called by muse, mutect2
- LTBP1 | c.1510G>C p.D504H (on ENST00000404816 / NM_206943.4; = p.D178H on NM_000627.4) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100617914, COSV63196653; called by muse, mutect2, varscan2
- LTBP2 | c.3173G>C p.R1058P | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.424); catalogued as COSV100000914; called by muse, mutect2, varscan2
- MACF1 | c.13456G>A p.E4486K (on ENST00000372915; = p.E2419K on NM_012090.5) | Missense Mutation (SNP) | VAF 34/408 reads (8%) | catalogued as COSV99246690; called by muse, mutect2
- MACF1 | c.16490A>G p.K5497R (on ENST00000372915; = p.K3430R on NM_012090.5) | Missense Mutation (SNP) | VAF 9/131 reads (7%) | catalogued as COSV99246693; called by muse, mutect2
- MASP2 | c.800T>A p.I267N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101280408; called by muse, mutect2, varscan2
- MATN4 | c.1003A>T p.S335C (on ENST00000372754; = p.S294C on NM_003833.4) | Missense Mutation (SNP) | VAF 7/67 reads (10%) | PolyPhen possibly damaging (0.75); catalogued as COSV100637167; called by muse, mutect2, varscan2
- MCTP2 | c.442G>T p.G148W | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV100537716; called by muse, mutect2, varscan2
- MED12 | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.632); catalogued as COSV100379812; called by muse, mutect2, varscan2
- METAP1 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56442640, COSV99595880; called by muse, mutect2, varscan2
- METTL3 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.135); catalogued as COSV99398580; called by muse, mutect2
- MGAM | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs782304559, COSV101516542, COSV71885748; called by muse, mutect2, varscan2
- MGAT4C | c.230C>G p.S77C | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); catalogued as COSV100153356; called by muse, mutect2
- MKRN3 | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs775128922, COSV100090889, COSV100091610; called by muse, mutect2, varscan2
- MORC4 | c.621T>A p.F207L | Missense Mutation (SNP) | VAF 7/171 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.119); catalogued as COSV99717587; called by muse, mutect2
- MRGBP | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV100978308, COSV65111613; called by muse, mutect2, varscan2
- MROH5 | c.3613C>A p.L1205I | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100267432; called by muse, mutect2, varscan2
- MS4A6E | c.349C>A p.L117M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100279231; called by muse, mutect2, varscan2
- MYADM | c.470G>T p.W157L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as COSV100425192; called by muse, mutect2, varscan2
- MYBPC1 | c.400G>T p.D134Y (on ENST00000550270 / NM_206820.2; = p.D159Y on NM_002465.4) | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as rs747919254, COSV100638262; called by muse, mutect2, varscan2
- MYF5 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV99953392; called by muse, mutect2, varscan2
- MYH4 | c.5715C>A p.H1905Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV55117188, COSV99702175, COSV99702583; called by muse, mutect2, varscan2
- MYH8 | c.5338G>C p.A1780P | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV101238758, COSV67964723; called by muse, mutect2, varscan2
- MYO15A | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99234352; called by muse, mutect2, varscan2
- N4BP3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV99200807; called by muse, mutect2, varscan2
- NAV3 | c.1787C>A p.S596Y | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV99895314; called by muse, mutect2, varscan2
- NAV3 | c.4843A>G p.S1615G | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV99895317; called by muse, mutect2, varscan2
- NEB | c.2200C>T p.Q734* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV99427677; called by muse, mutect2, varscan2
- NELFB | c.1532A>G p.H511R | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100547029; called by muse, mutect2, varscan2
- NES | c.1313C>A p.A438D | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.368); catalogued as COSV100957982; called by muse, mutect2, varscan2
- NKAIN2 | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.175); catalogued as COSV100864094; called by muse, mutect2, varscan2
- NLGN2 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV100081265; called by muse, mutect2, varscan2
- NLGN4X | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 13/106 reads (12%) | catalogued as COSV99323775; called by muse, mutect2, varscan2
- NLRP10 | c.446C>T p.S149F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as rs1266494490, COSV100149958; called by muse, mutect2, varscan2
- NLRP13 | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100738504; called by muse, mutect2, varscan2
- NOD2 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs201790577, COSV100318849, COSV56049522; called by muse, mutect2, varscan2
- NPY2R | c.712T>C p.S238P | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV100279899, COSV61527207; called by muse, mutect2
- NRCAM | c.3179C>T p.A1060V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs868280660, COSV100695440; called by muse, mutect2, varscan2
- NRXN1 | c.4237C>A p.L1413M | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV60524852; called by muse, mutect2, varscan2
- NRXN1 | c.3716C>T p.A1239V | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as COSV100640693; called by muse, mutect2, varscan2
- NRXN2 | c.2933T>A p.V978E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99635670; called by muse, mutect2, varscan2
- NSDHL | c.542G>T p.R181M | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV100938687; called by muse, mutect2, varscan2
- NTRK2 | c.794C>A p.S265Y | Missense Mutation (SNP) | VAF 45/233 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV99458415; called by muse, mutect2, varscan2
- NUDCD1 | c.1623G>T p.Q541H | Missense Mutation (SNP) | VAF 112/413 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99517676; called by muse, mutect2, varscan2
- OBSCN | c.11396C>A p.A3799D | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.291); catalogued as COSV99484000; called by muse, mutect2
- OR13C2 | c.708A>T p.K236N | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101604890; called by muse, mutect2
- OR1C1 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as COSV101376280, COSV68715856; called by muse, mutect2, varscan2
- OR2B6 | c.488C>A p.T163N | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99773842; called by muse, mutect2
- OR2M5 | c.836C>A p.T279N | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV100822877; called by muse, mutect2
- OR2W1 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV101013941; called by muse, mutect2, varscan2
- OR51G2 | c.466C>A p.R156S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs773289689, COSV100432236, COSV58993411; called by muse, mutect2, varscan2
- OR56B1 | c.102C>A p.H34Q | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV100402518; called by muse, mutect2, varscan2
- OR5M3 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100392685; called by muse, mutect2, varscan2
- OR6B3 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60113010; called by muse, mutect2, varscan2
- OR6B3 | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100097644; called by muse, mutect2, varscan2
- OR8B2 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1482220398, COSV100899501; called by muse, mutect2
- OSCAR | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs368658849, COSV99500077; called by muse, mutect2, varscan2
- OTOGL | c.2414G>T p.R805M (on ENST00000547103; = p.R796M on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV101509498; called by muse, mutect2
- PAPPA | c.3423C>G p.N1141K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV100075224; called by muse, mutect2, varscan2
- PARD3B | c.306T>A p.D102E | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.999); catalogued as rs1559306877, COSV100595105; called by muse, mutect2, varscan2
- PCDH11X | c.419C>A p.P140Q | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV100014987; called by muse, mutect2, varscan2
- PCDH15 | c.4855C>A p.L1619I (on ENST00000644397 / NM_001354429.2; = p.L1561I on NM_001142771.2) | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.103); catalogued as rs756007561, COSV100905635; called by muse, mutect2, varscan2
- PCDH15 | c.2081G>T p.R694M | Missense Mutation (SNP) | VAF 47/251 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99054657; called by muse, mutect2, varscan2
- PCDH19 | c.3377G>T p.S1126I (on ENST00000373034 / NM_001184880.2; = p.S1078I on NM_020766.3) | Missense Mutation (SNP) | VAF 47/219 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV99720723; called by muse, mutect2, varscan2
- PCDHB4 | c.2156C>G p.A719G | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.394); catalogued as COSV99522492; called by muse, mutect2, varscan2
- PCDHB5 | c.1870C>A p.R624S | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1307932821, COSV50650806, COSV99169467; called by muse, mutect2, varscan2
- PCDHB6 | c.1460C>A p.S487* | Nonsense Mutation (SNP) | VAF 12/312 reads (4%) | catalogued as COSV50689487; called by muse, mutect2
- PCDHGA9 | c.643T>A p.S215T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.023); catalogued as COSV99546353; called by muse, mutect2
- PCLO | c.4985G>T p.G1662V | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100437472, COSV61676817; called by muse, mutect2, varscan2
- PCM1 | c.542A>G p.N181S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.771); catalogued as rs749351444, COSV100279566; called by muse, mutect2, varscan2
- PDCD5 | c.331T>C p.F111L | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99694797; called by muse, mutect2, varscan2
- PDE5A | c.2117T>C p.I706T | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as rs1421081840, COSV99309183; called by muse, mutect2
- PFKP | c.1267G>C p.A423P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.98); catalogued as COSV101127509, COSV66899065; called by muse, varscan2
- PHF21B | c.764C>A p.P255Q | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV100504098; called by muse, mutect2, varscan2
- PIK3C2B | c.4265C>T p.S1422F | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.972); catalogued as rs998376628, COSV100916215; called by muse, mutect2, varscan2
- PLCH1 | c.3118G>A p.G1040R (on ENST00000340059 / NM_001130960.2; = p.G1032R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV58192619; called by muse, mutect2, varscan2
- PLCXD2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.871); catalogued as rs373550772, COSV67340381; called by muse, mutect2
- PLG | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99805089, COSV99805260; called by muse, mutect2
- PLK2 | c.194C>G p.S65W | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.367); catalogued as COSV99956268; called by muse, mutect2
- PLPP7 | c.706C>A p.H236N | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.499); catalogued as COSV100953179; called by muse, mutect2, varscan2
- PLPPR4 | c.1879C>A p.P627T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV100926918, COSV64567628; called by muse, mutect2, varscan2
- PPP1R3A | c.1198T>C p.C400R | Missense Mutation (SNP) | VAF 49/274 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV99494229; called by muse, mutect2, varscan2
- PRAME | c.1229C>A p.T410N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.516); catalogued as COSV101287237; called by muse, mutect2, varscan2
- PRR16 | c.268T>C p.S90P (on ENST00000407149 / NM_001300783.2; = p.S67P on NM_016644.2) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV101087931; called by muse, mutect2
- PSEN2 | c.1228A>C p.K410Q | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100423278; called by muse, mutect2, varscan2
- PTCD1 | c.1213A>G p.R405G | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99464517; called by muse, mutect2, varscan2
- PTPRM | c.3731A>G p.N1244S | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1241950162, COSV100160203; called by muse, mutect2
- RAB6D | c.764G>T p.*255Lext*61 | Nonstop Mutation (SNP) | VAF 17/142 reads (12%) | catalogued as rs533583829; called by muse, mutect2, varscan2
- RADX | c.1228G>T p.G410C | Missense Mutation (SNP) | VAF 11/160 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65319751; called by muse, mutect2
- RB1CC1 | c.199G>T p.D67Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99212918; called by muse, mutect2
- RBFOX1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs755458164, COSV60948155; called by muse, mutect2, varscan2
- RGS12 | c.2833G>C p.D945H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100123335; called by muse, mutect2, varscan2
- RHBDF1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs766428025, COSV51953757; called by muse, mutect2
- RP1L1 | c.1956C>A p.S652R | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV101223595; called by muse, varscan2
- RP1L1 | c.1868G>T p.G623V | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV101223597, COSV66759368; called by muse, varscan2
- RTL9 | c.271C>A p.L91I | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.772); catalogued as COSV101511790; called by muse, mutect2
- RTP5 | c.1521G>C p.K507N | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV100574801; called by muse, mutect2
- RYR2 | c.11206G>T p.A3736S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100771740, COSV100772724; called by muse, mutect2, varscan2
- SATL1 | c.174A>C p.Q58H (on ENST00000395409; = p.Q245H on NM_001012980.2) | Missense Mutation (SNP) | VAF 25/210 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.839); catalogued as COSV100261099, COSV60578054; called by muse, mutect2, varscan2
- SCARA5 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.176); catalogued as COSV100108074; called by muse, mutect2, varscan2
- SCG2 | c.1424C>G p.S475W | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV100544905; called by muse, mutect2, varscan2
- SCN11A | c.2648T>A p.L883Q | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.228); catalogued as COSV100182483; called by muse, mutect2, varscan2
- SEMA5B | c.434A>T p.Y145F | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV99533137; called by muse, mutect2
- SF3A1 | c.406G>T p.V136L | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.785); catalogued as COSV99305706; called by muse, mutect2, varscan2
- SFRP2 | c.198C>A p.H66Q | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99923455; called by muse, mutect2, varscan2
- SHC4 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs757388167, COSV100195301; called by muse, mutect2, varscan2
- SHISA3 | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100069925; called by mutect2, varscan2
- SLC13A4 | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1197413306, COSV100818855, COSV100818947; called by muse, mutect2
- SLC39A12 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV101070140, COSV101070192; called by muse, mutect2, varscan2
- SLC44A5 | c.1976G>T p.G659V | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1469685280, COSV100901837; called by muse, mutect2
- SLCO6A1 | c.164C>A p.P55Q | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as COSV101134946, COSV65805415; called by muse, mutect2
- SLITRK4 | c.1417C>A p.P473T | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV100567514; called by muse, mutect2, varscan2
- SMARCA1 | c.2764G>T p.G922* | Nonsense Mutation (SNP) | VAF 24/192 reads (13%) | catalogued as COSV100946711; called by muse, mutect2, varscan2
- SP140L | c.1277A>T p.H426L | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99707647; called by mutect2, varscan2
- SPHKAP | c.4917del p.T1640Pfs*16 (on ENST00000392056 / NM_001142644.2; = p.T1611Pfs*16 on NM_030623.3) | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | catalogued as COSV60879318; called by mutect2, varscan2
- SPIN2A | c.593C>A p.T198K | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100888047; called by mutect2, varscan2
- SPRY3 | c.319C>A p.P107T | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.04); catalogued as COSV100249541; called by muse, mutect2, varscan2
- SPRY3 | c.320C>A p.P107H | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100249544; called by muse, mutect2, varscan2
- SRFBP1 | c.916G>T p.E306* | Nonsense Mutation (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100232972; called by muse, mutect2
- SRMS | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53915822, COSV53916250; called by muse, mutect2, varscan2
- SRPK3 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.028); catalogued as rs782697914, COSV99473414; called by muse, mutect2
- SSTR3 | c.1251C>A p.Y417* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV60730068; called by muse, mutect2, varscan2
- ST6GALNAC5 | c.527A>T p.Y176F | Missense Mutation (SNP) | VAF 25/137 reads (18%) | PolyPhen probably damaging (0.909); catalogued as COSV100603046; called by muse, mutect2, varscan2
- STAMBP | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV100277801; called by muse, mutect2, varscan2
- STOX1 | c.1250del p.G417Vfs*55 | Frame Shift Del (DEL) | VAF 47/225 reads (21%) | catalogued as rs770352026; called by mutect2, pindel, varscan2
- SYNE3 | c.1226T>C p.L409P | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100516447; called by muse, mutect2, varscan2
- SYT10 | c.44A>G p.K15R | Missense Mutation (SNP) | VAF 23/256 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV99951958; called by muse, mutect2
- TBATA | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.456); catalogued as rs776723435, COSV100165508; called by muse, mutect2
- TBC1D1 | c.1555A>G p.R519G | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs747266033, COSV99792129; called by muse, mutect2, varscan2
- TCEAL5 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV65503413; called by muse, mutect2, varscan2
- TENM1 | c.4243C>A p.L1415M | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.208); catalogued as COSV100950867, COSV64441145; called by muse, mutect2, varscan2
- TENM1 | c.3400G>T p.G1134* | Nonsense Mutation (SNP) | VAF 41/341 reads (12%) | catalogued as COSV100950869; called by muse, mutect2, varscan2
- TENM4 | c.8006A>G p.Q2669R | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.953); catalogued as COSV99578926; called by muse, mutect2
- TET1 | c.1607C>A p.A536D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV101018856; called by muse, mutect2, varscan2
- TF | c.1685G>T p.G562V | Missense Mutation (SNP) | VAF 12/182 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs41296590, COSV99396429; ClinVar: likely benign; called by muse, mutect2
- TGM6 | c.1926G>T p.M642I | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1236581752, COSV99172750; called by muse, mutect2, varscan2
- TM9SF3 | c.970A>G p.M324V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs761703623, COSV100951885; called by muse, mutect2, varscan2
- TNRC6B | c.1904A>T p.D635V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100110459; called by muse, mutect2, varscan2
- TOP2A | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV101396003, COSV101396380; called by muse, mutect2
- TRO | c.3078T>A p.N1026K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV99437265; called by muse, mutect2
- TRPM6 | c.5593T>A p.Y1865N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100666944; called by muse, mutect2, varscan2
- TSPOAP1 | c.1376G>T p.R459L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99272628; called by muse, mutect2, varscan2
- TTL | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV99271604; called by muse, mutect2, varscan2
- TTLL9 | c.888G>T p.R296S | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100207244; called by muse, mutect2, varscan2
- TXLNB | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100625163; called by muse, mutect2
- UBAP2 | c.1873A>G p.R625G | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.577); catalogued as COSV100671925; called by muse, mutect2, varscan2
- UGT2A1 | c.1003T>A p.W335R | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684869; called by muse, mutect2, varscan2
- UGT2B17 | c.7C>A p.L3M | Missense Mutation (SNP) | VAF 51/446 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100497302; called by muse, mutect2, varscan2
- UGT2B28 | c.1170G>T p.M390I | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as COSV100159046; called by muse, mutect2, varscan2
- VMP1 | c.579G>T p.M193I | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV51872282, COSV99230987; called by muse, mutect2
- WDR44 | c.706C>A p.P236T | Missense Mutation (SNP) | VAF 36/251 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV99561925; called by muse, mutect2, varscan2
- WDR44 | c.1495C>G p.Q499E | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as COSV99561926; called by muse, mutect2, varscan2
- WNK1 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV100268526; called by muse, mutect2, varscan2
- XKR9 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.219); catalogued as rs940275155, COSV101281974; called by muse, mutect2, varscan2
- ZBTB9 | c.914G>T p.G305V | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs769382866, COSV101221803; called by muse, mutect2
- ZC3H12B | c.1949G>T p.G650V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs761811198, COSV100162008; called by muse, mutect2, varscan2
- ZCCHC12 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs775616873, COSV100038666; called by muse, mutect2
- ZFHX4 | c.7539C>A p.H2513Q | Missense Mutation (SNP) | VAF 21/201 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.245); catalogued as COSV99267272; called by muse, mutect2
- ZFPM2 | c.2727C>G p.Y909* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV101023518; called by muse, mutect2, varscan2
- ZMAT1 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100858924; called by muse, mutect2, varscan2
- ZNF185 | c.599C>A p.A200D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV100248652; called by muse, mutect2, varscan2
- ZNF226 | c.1817G>A p.C606Y | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.957); catalogued as rs1164662940, COSV100335244; called by muse, mutect2, varscan2
- ZNF235 | c.1042A>G p.T348A | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs1407905393, COSV99349709; called by muse, mutect2, varscan2
- ZNF33A | c.1022C>T p.S341L (on ENST00000458705 / NM_006974.3; = p.S342L on NM_006954.2) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.824); catalogued as rs1183390687, COSV100276189; called by muse, mutect2
- ZNF479 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs782397414, COSV58635674, COSV58644232; called by muse, mutect2, varscan2
- ZNF484 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 7/188 reads (4%) | catalogued as COSV100214860; called by muse, mutect2
- ZNF527 | c.836G>A p.C279Y | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100648778; called by muse, mutect2, varscan2
- ZNF528 | c.980G>T p.C327F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV100846748; called by muse, mutect2, varscan2
- ZNF574 | c.2674G>A p.V892I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.031); catalogued as COSV55902346, COSV99726478; called by muse, mutect2
- ZNF624 | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV60940997; called by muse, mutect2, varscan2
- ZNF628 | c.2449G>T p.G817W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1233857767, COSV99220277; called by muse, mutect2, varscan2
- ZNF711 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.935); catalogued as COSV99341578; called by muse, mutect2, varscan2
- ZNF740 | c.204T>A p.D68E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV99915022; called by muse, mutect2
- ZNF92 | c.1009G>T p.G337W (on ENST00000328747 / NM_152626.4; = p.G268W on NM_007139.4) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100165966; called by muse, mutect2, varscan2
- ASB4 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATP13A3 | c.3080G>T p.W1027L | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC74A | c.1098G>T p.Q366H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- CD81 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FBN2 | c.3022del p.D1008Mfs*99 | Frame Shift Del (DEL) | VAF 14/112 reads (13%) | called by mutect2, pindel
- GDF2 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- H2BC21 | c.148del p.H50Tfs*14 | Frame Shift Del (DEL) | VAF 34/354 reads (10%) | called by mutect2, pindel
- IGKV1D-16 | c.345T>G p.S115R | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- IRGC | c.849dup p.G284Rfs*8 | Frame Shift Ins (INS) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- ITGBL1 | c.1336del p.E446Sfs*79 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | called by mutect2, pindel, varscan2
- KLHL13 | c.1432del p.H478Tfs*12 | Frame Shift Del (DEL) | VAF 23/211 reads (11%) | called by mutect2, pindel, varscan2
- LBP | c.489C>G p.I163M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MCOLN2 | c.1399G>T p.A467S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); called by muse, mutect2
- MEX3C | c.1931G>T p.C644F | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHF1 | c.1465G>A p.A489T (on ENST00000374516 / NM_024165.3; = p.V453= on NM_002636.5) | Missense Mutation (SNP) | VAF 19/214 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.014); called by muse, mutect2
- RBBP9 | c.351del p.W118Gfs*57 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | called by mutect2, pindel
- SOX7 | c.388G>T p.D130Y | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SPPL2B | c.1598del p.P533Rfs*53 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- TMCC3 | c.230dup p.V78Gfs*8 | Frame Shift Ins (INS) | VAF 18/172 reads (10%) | called by pindel, varscan2
- TRBV24-1 | c.153G>T p.M51I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ZNF292 | c.4297A>C p.N1433H | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACAN | c.930C>T p.P310= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV100719201; called by mutect2, varscan2
- ACTL9 | c.942C>G p.G314= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as COSV100185537; called by muse, mutect2, varscan2
- ADCY4 | c.2823T>A p.S941= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV100156833; called by muse, mutect2, varscan2
- AHNAK2 | c.9268C>T p.L3090= | Silent (SNP) | VAF 10/244 reads (4%) | catalogued as COSV100318858; called by muse, mutect2
- AHNAK2 | c.2112G>A p.K704= | Silent (SNP) | VAF 16/278 reads (6%) | catalogued as rs1246702766; called by muse, mutect2
- ANGPT4 | c.294G>C p.T98= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as COSV101124868, COSV67922324; called by muse, mutect2, varscan2
- ANK2 | c.7500G>A p.T2500= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as rs374941639, COSV100003452; ClinVar: likely benign; called by muse, mutect2, varscan2
- AOC1 | c.1515G>A p.L505= | Silent (SNP) | VAF 12/124 reads (10%) | catalogued as COSV100710962; called by muse, mutect2, varscan2
- ASTN2 | c.1296G>A p.V432= (on ENST00000313400 / NM_001365069.1; = p.V381= on NM_014010.5) | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1218625637, COSV100530227; called by muse, mutect2
- ASTN2 | c.957C>A p.T319= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as COSV100530228; called by muse, mutect2, varscan2
- ATP9B | c.2724G>C p.T908= | Silent (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100304160; called by muse, mutect2, varscan2
- BNIP1 | c.597G>T p.L199= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99199446; called by muse, mutect2
- C1QTNF1 | c.441C>A p.A147= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV59262065; called by muse, mutect2, varscan2
- CD28 | c.246G>T p.T82= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV100142571; called by muse, mutect2, varscan2
- CDH23 | c.7419G>T p.L2473= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99823643; called by muse, mutect2, varscan2
- CDH9 | c.2292T>C p.Y764= | Silent (SNP) | VAF 26/186 reads (14%) | catalogued as rs747743675, COSV50318199, COSV99152079; called by muse, mutect2, varscan2
- CEP170 | c.156G>A p.T52= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs376438499, COSV100839765; called by muse, mutect2, varscan2
- COL15A1 | c.2175C>T p.P725= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV100897982; called by muse, mutect2, varscan2
- COL6A3 | c.849G>T p.V283= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as COSV99801215; called by muse, mutect2, varscan2
- COL7A1 | c.1146G>T p.L382= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV100097629; called by muse, mutect2, varscan2
- DDX17 | c.744A>T p.L248= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV99318962; called by muse, mutect2
- EIF4G3 | c.2493G>T p.V831= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV51680073, COSV99945603; called by muse, mutect2, varscan2
- EP400 | c.9189G>T p.V3063= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100202201; called by muse, mutect2
- EPB41L1 | c.525C>T p.F175= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs774456412, COSV52440488, COSV99148757; called by muse, mutect2
- EXOC2 | c.1938C>T p.F646= | Silent (SNP) | VAF 17/134 reads (13%) | catalogued as COSV57870565; called by muse, mutect2, varscan2
- FAM135B | c.1908C>A p.T636= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV99427294; called by muse, mutect2
- FASTKD5 | c.2196G>T p.V732= | Silent (SNP) | VAF 21/173 reads (12%) | catalogued as COSV99418556; called by muse, mutect2, varscan2
- FBXL7 | c.957G>T p.L319= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100310757; called by muse, mutect2, varscan2
- FGF23 | c.477C>T p.S159= | Silent (SNP) | VAF 18/102 reads (18%) | catalogued as rs1390422854, COSV99426691; called by muse, mutect2, varscan2
- FHL5 | c.297C>T p.S99= | Silent (SNP) | VAF 7/98 reads (7%) | catalogued as COSV100459776; called by muse, mutect2
- GPAT3 | c.1281T>C p.I427= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV100023280; called by mutect2, varscan2
- GRIA4 | c.348C>T p.S116= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as COSV99234342; called by muse, mutect2, varscan2
- GRIN2A | c.3456G>A p.Q1152= | Silent (SNP) | VAF 16/176 reads (9%) | catalogued as rs1085307669, COSV58021504; called by muse, mutect2
- GRM8 | c.294G>T p.L98= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV58886047; called by muse, mutect2, varscan2
- GUSB | c.1419G>A p.L473= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs745662610, COSV100512759; called by muse, mutect2
- HIVEP2 | c.3960G>T p.S1320= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV50023580, COSV99175326; called by muse, mutect2, varscan2
- KAT6A | c.958C>T p.L320= | Silent (SNP) | VAF 34/224 reads (15%) | catalogued as COSV99705844; called by muse, mutect2, varscan2
- LRFN5 | c.456G>T p.L152= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV53250050, COSV99985355; called by muse, mutect2, varscan2
- LUZP2 | c.543G>T p.L181= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100421280; called by muse, mutect2
- MAGEB6 | c.1041G>T p.V347= | Silent (SNP) | VAF 19/174 reads (11%) | catalogued as COSV100983860; called by muse, mutect2, varscan2
- MAP7D2 | c.564C>T p.S188= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs370327382, COSV65527489; called by muse, mutect2, varscan2
- MGAT4C | c.1137T>C p.F379= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV100153355; called by muse, mutect2, varscan2
- MLLT10 | c.930T>C p.T310= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs1343615656, COSV100308761; called by muse, mutect2, varscan2
- MMRN1 | c.927G>A p.Q309= | Silent (SNP) | VAF 58/297 reads (20%) | catalogued as COSV53337939, COSV99307735; called by muse, mutect2, varscan2
- MTMR12 | c.1746A>G p.E582= | Silent (SNP) | VAF 8/131 reads (6%) | catalogued as COSV99374034; called by muse, mutect2
- MTUS2 | c.1566C>A p.T522= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV101462357, COSV101462374; called by muse, mutect2, varscan2
- MUC16 | c.7251A>T p.T2417= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV101201481; called by muse, varscan2
- MUC6 | c.5148C>A p.P1716= | Silent (SNP) | VAF 28/688 reads (4%) | catalogued as COSV101424782; called by muse, mutect2
- MYH15 | c.3831G>A p.K1277= | Silent (SNP) | VAF 30/180 reads (17%) | catalogued as COSV99844246; called by muse, mutect2, varscan2
- MYPN | c.219C>T p.D73= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV100590588; called by muse, mutect2, varscan2
- MYT1 | c.208C>T p.L70= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100115415; called by muse, mutect2, varscan2
- NCAM2 | c.1014G>T p.V338= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1159469992, COSV99525133; called by muse, mutect2, varscan2
- NEFH | c.2226A>G p.E742= | Silent (SNP) | VAF 18/141 reads (13%) | catalogued as COSV100151805; called by muse, mutect2, varscan2
- NFATC4 | c.960C>A p.A320= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV99151035; called by muse, mutect2, varscan2
- NKAP | c.150C>A p.S50= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as COSV101004294, COSV65057008; called by muse, mutect2
- NKRF | c.819C>G p.L273= | Silent (SNP) | VAF 16/174 reads (9%) | catalogued as COSV100441879; called by muse, mutect2, varscan2
- NPAS3 | c.1335C>T p.I445= (on ENST00000356141 / NM_001164749.2; = p.I413= on NM_022123.3) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as rs201421063, COSV100640284; called by muse, mutect2, varscan2
- NPAS3 | c.2037C>A p.P679= (on ENST00000356141 / NM_001164749.2; = p.P647= on NM_022123.3) | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as rs762269416, COSV100640646; called by muse, mutect2, varscan2
- NRBP1 | c.561C>T p.A187= | Silent (SNP) | VAF 23/89 reads (26%) | catalogued as COSV99275278; called by muse, mutect2, varscan2
- NT5C1A | c.1065C>A p.P355= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99348665; called by muse, mutect2, varscan2
- OR2M5 | c.837C>A p.T279= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as COSV100822878; called by muse, mutect2
- PAXBP1 | c.1041C>T p.Y347= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as rs61751893; called by muse, mutect2
- PCDHA1 | c.1536G>C p.A512= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100974465; called by muse, mutect2, varscan2
- PCDHGA12 | c.2205G>A p.A735= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV99338024; called by muse, mutect2, varscan2
- PCLO | c.3645T>C p.P1215= | Silent (SNP) | VAF 58/265 reads (22%) | catalogued as COSV100429517, COSV100437475; called by muse, mutect2, varscan2
- PDE7B | c.402G>A p.L134= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as rs1472318482, COSV57502446; called by muse, mutect2
- PIK3C2B | c.3453C>T p.F1151= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV100916216; called by muse, mutect2, varscan2
- PLA2R1 | c.3360A>G p.E1120= | Silent (SNP) | VAF 5/129 reads (4%) | called by muse, mutect2
- RIMBP2 | c.672G>A p.V224= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99900417; called by muse, mutect2
- SEC31B | c.2643A>G p.V881= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs751780059, COSV100947456; called by muse, mutect2, varscan2
- SHC3 | c.681G>A p.L227= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV101012060; called by muse, mutect2
- SLC16A6 | c.42G>A p.V14= | Silent (SNP) | VAF 16/68 reads (24%) | catalogued as COSV100517406; called by muse, mutect2, varscan2
- SNTG1 | c.1116G>A p.V372= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as rs189241890, COSV52456854; called by mutect2, varscan2
- SPTA1 | c.7254C>A p.G2418= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100779081; called by muse, mutect2, varscan2
- SUGT1 | c.750G>A p.E250= (on ENST00000343788 / NM_001130912.3; = p.E218= on NM_006704.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV100139682; called by muse, mutect2, varscan2
- SUPT20HL1 | c.702G>A p.P234= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs1293123484; called by muse, mutect2, varscan2
- TAB1 | c.882G>A p.K294= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV99336278; called by muse, mutect2, varscan2
- TENM1 | c.2892C>A p.V964= | Silent (SNP) | VAF 17/149 reads (11%) | catalogued as COSV100950870; called by muse, mutect2, varscan2
- TFDP1 | c.348A>G p.L116= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as rs1341454045, COSV100946023; called by muse, mutect2, varscan2
- TMEM100 | c.114T>C p.S38= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- TMEM94 | c.3090C>T p.S1030= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100050922; called by muse, mutect2, varscan2
- TRPM3 | c.5124C>T p.S1708= (on ENST00000357533 / NM_001366142.2; = p.S1563= on NM_020952.6) | Silent (SNP) | VAF 14/131 reads (11%) | catalogued as COSV100678659; called by muse, mutect2, varscan2
- VIRMA | c.3054G>T p.T1018= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV99889405; called by muse, mutect2, varscan2
- WDR49 | c.1860G>C p.L620= (on ENST00000308378 / NM_001366158.1; = p.L961= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/270 reads (17%) | catalogued as COSV100393792; called by muse, mutect2, varscan2
- XIRP2 | c.5553A>G p.V1851= (on ENST00000628543; = p.V2026= on NM_152381.6) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV99747082; called by muse, mutect2, varscan2
- ZBTB22 | c.525C>T p.S175= | Silent (SNP) | VAF 9/75 reads (12%) | catalogued as rs1344199367, COSV56468063; called by muse, mutect2, varscan2
- ZDHHC2 | c.567A>G p.T189= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV100025156; called by muse, mutect2, varscan2
- ZNF331 | c.282C>T p.R94= | Silent (SNP) | VAF 26/99 reads (26%) | catalogued as COSV99467907; called by muse, mutect2, varscan2
- ZNF551 | c.798T>G p.L266= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as COSV99990325; called by muse, mutect2, varscan2
- MAP4 | c.1999+5254G>T | Intron (SNP) | VAF 14/221 reads (6%) | catalogued as COSV99276222; called by muse, mutect2
- SERPINA13P | n.777G>T | RNA (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- SNORD113-5 | n.10G>A | RNA (SNP) | VAF 63/216 reads (29%) | called by muse, mutect2, varscan2
- SUGCT | c.1090-65334T>C | Intron (SNP) | VAF 10/73 reads (14%) | catalogued as rs1166115009, COSV100004456; called by muse, mutect2, varscan2
- TAFA3 | c.266-49C>A | Intron (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100721503, COSV62624856; called by muse, mutect2, varscan2
- ZC3H14 | c.1280-1821G>T | Intron (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99193245; called by muse, mutect2, varscan2
